Gene-level copy-number profile of tumor specimen TCGA-B9-4116-01A from TCGA case TCGA-B9-4116, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 75.8 years (27,692 days).
Specimen TCGA-B9-4116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.a28c2e97-79d6-4e2e-a879-85a521ae89b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B9-4116-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eadb0f38-4d90-4b17-8c79-9dff9aac63f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,843; copy number 2: 52,053; copy number 3: 1,211; copy number 4: 164; copy number 6: 43; copy number 7: 37; copy number 8: 315; copy number 9: 124; copy number 11: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B9-4116-01A-02D-1348-01): tumor purity 0.82, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 544 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:86,216,785–86,864,884, 2 genes, copy number 9 (within-gene range 2–9): SOCS5P1, GRM3.
- chr7:87,833,568–89,338,528, 18 genes, copy number 8 (within-gene range 2–8): SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:89,754,620–92,590,393, 48 genes, copy number 8–11: RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B.
- chr7:93,424,486–95,615,132, 46 genes, copy number 9: CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4.
- chr7:100,826,820–104,208,047, 106 genes, copy number 8 (broad region; genes not listed).
- chr7:106,774,955–106,908,980, 3 genes, copy number 7 (within-gene range 1–7): LINC02577, RNA5SP236, PIK3CG.
- chr7:107,563,971–107,717,809, 8 genes, copy number 6–7 (within-gene range 1–7): DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4.
- chr7:108,023,548–108,995,029, 12 genes, copy number 7 (within-gene range 3–7): LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr7:109,959,218–109,999,624, 2 genes, copy number 7: EIF3IP1, RPL3P8.
- chr7:110,590,082–110,592,204, 1 gene, copy number 7: AC073326.2.
- chr7:112,206,695–112,521,670, 12 genes, copy number 7: ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14.
- chr7:113,876,777–122,995,700, 115 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr7:124,032,126–124,790,689, 9 genes, copy number 8 (within-gene range 1–8): AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77.
- chr7:127,652,194–130,791,724, 113 genes, copy number 8–9 (within-gene range 1–9) (broad region; genes not listed).
- chr7:130,822,868–130,930,682, 7 genes, copy number 9 (within-gene range 1–9): AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1.
- chr7:131,110,096–131,496,632, 1 gene, copy number 6 (within-gene range 1–6): MKLN1.
- chr7:131,309,469–131,558,217, 4 genes, copy number 6: MKLN1-AS, AC008264.2, PODXL, AC008264.1.
- chr7:137,164,043–139,109,720, 37 genes, copy number 6 (within-gene range 2–6): AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1, DGKI, AC090498.1, AC009245.1, CREB3L2, CREB3L2-AS1, AKR1D1, AC009263.1, AC024082.1, AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2, Y_RNA, AC083867.1, AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1.

Autosomal genes at a single copy (total copy number 1): 5,843. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
